FM case AD11471 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/22e9ddb7-a7a4-41e2-8669-586c844aaa00

Female, 56.5 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
